Somatic mutation profile of tumor specimen TCGA-CV-6934-01A (aliquot TCGA-CV-6934-01A-11D-1912-08) from TCGA case TCGA-CV-6934, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 66.2 years (24,180 days).
Specimen TCGA-CV-6934-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eabda6ad-4bad-45e6-a54b-21d0dec96eb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6934-10A (Blood Derived Normal), aliquot TCGA-CV-6934-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/077b463d-c44a-4bce-875d-5e2e5e323c4b

The open-access MAF lists 99 somatic variants for this specimen: 77 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 20, Nonsense Mutation 3, Frame Shift Del 2, Frame Shift Ins 2, Splice Site 2, 5'Flank 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 21/50 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520007, COSV52665440, COSV52677268, COSV52688506; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA5 | c.2659A>G p.K887E | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.388); catalogued as COSV101201266; called by muse, mutect2, varscan2
- ABCG2 | c.404C>A p.T135K | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99419446, COSV99420015; called by muse, mutect2
- ACBD3 | c.1511A>G p.Y504C | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100831135; called by muse, mutect2, varscan2
- ADGRG4 | c.4181T>C p.V1394A | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.074); catalogued as rs1297697538, COSV99796489; called by muse, mutect2, varscan2
- AFDN | c.847G>C p.E283Q | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.948); catalogued as COSV100653457; called by muse, mutect2
- AHNAK2 | c.12046C>A p.L4016I | Missense Mutation (SNP) | VAF 119/369 reads (32%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.729); catalogued as COSV100318768; called by muse, mutect2, varscan2
- ARID1B | c.4978C>G p.L1660V | Missense Mutation (SNP) | VAF 80/346 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99271519; called by muse, mutect2, varscan2
- ATG4A | c.842A>G p.H281R | Missense Mutation (SNP) | VAF 75/289 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100619859; called by muse, mutect2, varscan2
- CACNA1H | c.4189G>A p.V1397M | Missense Mutation (SNP) | VAF 42/202 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1186328765, COSV61991376; called by muse, mutect2, varscan2
- CCNB3 | c.905C>G p.P302R | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV99329700; called by muse, mutect2
- CEACAM18 | c.916A>T p.I306F | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as COSV101140653; called by muse, mutect2, varscan2
- CEMIP2 | c.309A>G p.I103M | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV100987496; called by muse, mutect2, varscan2
- CHI3L2 | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 29/113 reads (26%) | catalogued as COSV100869319, COSV63874025; called by muse, mutect2, varscan2
- CNTN2 | c.1729G>A p.A577T | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.746); catalogued as rs1196499204, COSV100085416; called by muse, mutect2, varscan2
- CRHBP | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57189511; called by muse, mutect2, varscan2
- CTRC | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1472934141, COSV65621091; called by muse, mutect2, varscan2
- CUBN | c.2111C>T p.S704L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.114); catalogued as rs761726613, COSV100911800, COSV100913410; called by muse, mutect2, varscan2
- DUSP29 | c.329G>C p.G110A | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs754004741, COSV100633396; called by muse, mutect2, varscan2
- DYNC2H1 | c.3067G>T p.E1023* | Nonsense Mutation (SNP) | VAF 7/60 reads (12%) | catalogued as COSV100519560; called by muse, mutect2, varscan2
- EMC9 | c.29C>G p.A10G | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99246471; called by muse, mutect2, varscan2
- ENPP4 | c.665A>G p.K222R | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.56); catalogued as rs1464894209, COSV100320436; called by muse, mutect2, varscan2
- EP400 | c.7204A>G p.K2402E | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100202084; called by muse, mutect2, varscan2
- ERI1 | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV99141412; called by muse, mutect2, varscan2
- HMMR | c.847T>G p.S283A | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.827); catalogued as COSV100701044; called by muse, mutect2, varscan2
- INTS8 | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.987); catalogued as COSV100569422; called by muse, mutect2, varscan2
- KCNT2 | c.3366C>A p.C1122* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | catalogued as COSV99656328; called by muse, mutect2, varscan2
- KCTD2 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs1319572990, COSV59368423; called by muse, varscan2
- LRGUK | c.1806G>C p.L602F | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV99604610; called by muse, mutect2, varscan2
- MAOB | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as rs776880004, COSV100956215; called by muse, mutect2, varscan2
- MAP2K5 | c.994C>A p.Q332K | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.094); catalogued as COSV99461732, COSV99462068; called by muse, mutect2, varscan2
- MAS1L | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.136); catalogued as COSV101009721; called by muse, mutect2, varscan2
- MBTD1 | c.1468C>G p.H490D | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100899321; called by muse, mutect2, varscan2
- METTL14 | c.673G>C p.A225P | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101183414; called by muse, mutect2
- MORC2 | c.1436C>T p.P479L (on ENST00000397641 / NM_001303256.3; = p.P417L on NM_014941.3) | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1426394911, COSV99310354; called by muse, mutect2, varscan2
- NBN | c.2207A>G p.E736G | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99619985; called by muse, mutect2, varscan2
- NEB | c.17575A>C p.S5859R | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99427162; called by muse, mutect2
- NPAT | c.1554A>T p.E518D | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.437); catalogued as COSV99586298; called by muse, mutect2, varscan2
- NUDT22 | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54176174, COSV99656017; called by muse, mutect2, varscan2
- OBSCN | c.3163G>A p.E1055K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.884); catalogued as rs1278352549, COSV52749325; called by muse, mutect2
- PHACTR4 | c.995C>G p.S332W (on ENST00000373839 / NM_001350159.2; = p.S342W on NM_023923.4) | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.563); catalogued as rs201435138, COSV65785262; called by muse, mutect2, varscan2
- PICALM | c.894-2A>T p.X298_splice | Splice Site (SNP) | VAF 22/98 reads (22%) | catalogued as COSV100708186; called by muse, mutect2, varscan2
- PMEL | c.568C>T p.H190Y | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs745467596, COSV100093360; called by muse, mutect2, varscan2
- PRSS23 | c.115G>A p.V39I | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1187213933, COSV99722563; called by muse, mutect2, varscan2
- RIPPLY2 | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV100860764; called by muse, mutect2, varscan2
- SAMD9L | c.2461G>A p.V821I | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs375447430; called by muse, mutect2, varscan2
- SEC24D | c.844G>C p.V282L | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99756691; called by muse, mutect2, varscan2
- SEL1L2 | c.1086T>A p.F362L | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV99533834; called by muse, mutect2, varscan2
- SIRPB1 | c.51G>T p.M17I | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV99683802; called by muse, mutect2, varscan2
- SLC9A1 | c.2191G>A p.D731N | Missense Mutation (SNP) | VAF 71/343 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV99849980; called by muse, mutect2, varscan2
- SOX2 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV57622761; called by muse, mutect2, varscan2
- TADA1 | c.896T>C p.L299P | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.809); catalogued as rs754739117, COSV100902365; called by muse, mutect2, varscan2
- TFAM | c.423A>T p.K141N | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100876096; called by muse, mutect2, varscan2
- TG | c.4295C>A p.T1432N | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.255); catalogued as rs765157522, COSV99602849; called by muse, mutect2, varscan2
- TGDS | c.768C>A p.N256K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV99725289; called by muse, mutect2, varscan2
- TLK1 | c.956G>C p.G319A | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100688738; called by muse, mutect2, varscan2
- TMTC1 | c.2615G>A p.R872Q (on ENST00000539277 / NM_001193451.2; = p.R764Q on NM_175861.3) | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs770031173, COSV55474922; called by muse, mutect2
- TRHDE | c.1226G>T p.W409L | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99672205; called by muse, mutect2, varscan2
- TTN | c.42209C>A p.A14070E (on ENST00000591111; = p.A6646E on NM_003319.4) | Missense Mutation (SNP) | VAF 16/105 reads (15%) | PolyPhen probably damaging (0.984); catalogued as COSV100590012; called by muse, mutect2, varscan2
- TTN | c.31742C>T p.T10581I (on ENST00000591111; = p.T9654I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/42 reads (10%) | PolyPhen benign (0.219); catalogued as COSV100626890; called by muse, mutect2, varscan2
- WASF2 | c.1300A>T p.S434C | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV101420815; called by muse, mutect2, varscan2
- XIRP2 | c.7930G>A p.E2644K (on ENST00000628543; = p.E2819K on NM_152381.6) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs867058212, COSV54690420; called by muse, mutect2, varscan2
- XRRA1 | c.1303A>C p.K435Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); catalogued as COSV100370063; called by muse, mutect2, varscan2
- ZDHHC5 | c.1931C>T p.P644L | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1226956353, COSV99762590; called by muse, mutect2, varscan2
- ZDHHC8 | c.616T>A p.F206I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100273150; called by muse, mutect2, varscan2
- ZKSCAN8 | c.236G>T p.W79L | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57640584; called by muse, mutect2, varscan2
- ZMYM4 | c.2171A>T p.N724I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.102); catalogued as COSV58912489; called by muse, mutect2, varscan2
- ZNF154 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750939344, COSV70744797; called by muse, mutect2, varscan2
- ZNF512 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.028); catalogued as rs752256195, COSV62677922; called by muse, mutect2, varscan2
- ZWILCH | c.1342-2A>T p.X448_splice | Splice Site (SNP) | VAF 5/59 reads (8%) | catalogued as COSV100328918; called by muse, mutect2
- AVL9 | c.1149dup p.I384Dfs*52 | Frame Shift Ins (INS) | VAF 6/51 reads (12%) | called by mutect2, pindel, varscan2
- CMTR2 | c.119_123del p.L40Qfs*2 | Frame Shift Del (DEL) | VAF 27/59 reads (46%) | called by mutect2, pindel, varscan2
- GTF3C4 | c.1720dup p.W574Lfs*4 | Frame Shift Ins (INS) | VAF 32/187 reads (17%) | called by mutect2, pindel, varscan2
- MAK | c.25del p.Q9Sfs*27 | Frame Shift Del (DEL) | VAF 14/97 reads (14%) | called by mutect2, pindel, varscan2
- TNK1 | c.1431T>A p.N477K (on ENST00000576812 / NM_001251902.2; = p.N472K on NM_003985.5) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TRBV3-1 | c.205A>C p.N69H | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); called by muse, mutect2
- TUBGCP6 | c.5271_5291del p.P1758_G1764del | In Frame Del (DEL) | VAF 15/98 reads (15%) | called by mutect2, pindel
- ANKFN1 | c.282C>T p.N94= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs201436645, COSV59441624; called by muse, mutect2, varscan2
- CASKIN2 | c.1257G>A p.G419= | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as rs1471722196, COSV100050847; called by muse, mutect2
- CTNND2 | c.2730C>T p.C910= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as rs764744996, COSV100479720, COSV58872802; called by muse, mutect2, varscan2
- DNAH10 | c.1158C>T p.T386= (on ENST00000409039; = p.T325= on NM_207437.3) | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as rs547195870, COSV101292572, COSV69000113; called by muse, mutect2, varscan2
- H3C7 | c.196C>T p.L66= | Silent (SNP) | VAF 17/142 reads (12%) | catalogued as COSV99769236; called by muse, mutect2, varscan2
- HLA-DMB | c.219G>A p.A73= | Silent (SNP) | VAF 17/118 reads (14%) | catalogued as rs1045763076, COSV66870836; called by muse, mutect2, varscan2
- LAMC1 | c.2835G>A p.G945= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV99280321; called by muse, mutect2, varscan2
- LMTK2 | c.2121C>T p.H707= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as COSV99807596; called by muse, mutect2, varscan2
- MC2R | c.127C>T p.L43= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100563162; called by muse, mutect2, varscan2
- NUP50 | c.423C>T p.S141= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as rs772692403, COSV100754394; called by muse, mutect2, varscan2
- PMEL | c.567C>T p.Y189= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as COSV100093362; called by muse, mutect2, varscan2
- RBAK | c.276A>G p.Q92= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV100806746; called by muse, mutect2
- SEZ6L2 | c.2202G>T p.L734= (on ENST00000308713 / NM_001114099.3; = p.L664= on NM_012410.4) | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100435788; called by muse, mutect2, varscan2
- SORCS3 | c.2226A>C p.S742= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as COSV100863773; called by muse, mutect2, varscan2
- SWAP70 | c.1084C>T p.L362= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100014080; called by muse, mutect2, varscan2
- TNXB | c.9573G>A p.T3191= (on ENST00000647633; = p.T2944= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as rs778066630, COSV64479719; called by muse, mutect2, varscan2
- YIPF2 | c.270C>T p.D90= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as rs1187632484, COSV99450296; called by muse, varscan2
- ZFHX4 | c.4050G>C p.P1350= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV50737398, COSV99266767; called by muse, mutect2, varscan2
- ZNF284 | c.855G>A p.K285= | Silent (SNP) | VAF 26/104 reads (25%) | catalogued as rs1431112319, COSV101399074; called by muse, mutect2, varscan2
- ZNF628 | c.2610G>A p.V870= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV99220251; called by muse, mutect2, varscan2
- MAGEA5 | n.375A>C | RNA (SNP) | VAF 39/183 reads (21%) | called by muse, mutect2, varscan2
- ZNFX1 | chr20:49280745 A>G | 5'Flank (SNP) | VAF 25/110 reads (23%) | called by muse, mutect2, varscan2
